Gene-level copy-number profile of tumor specimen TCGA-2Y-A9GU-01A from TCGA case TCGA-2Y-A9GU, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 55.3 years (20,187 days).
Specimen TCGA-2Y-A9GU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.afd9c5ab-fb6e-416b-988c-8e6876061b26.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Y-A9GU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5eabd4a7-9456-4585-a46a-2ffd4dbc84ac

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,469; copy number 3: 5,349; copy number 4: 26,861; copy number 5: 14,358; copy number 6: 4,436; copy number 7: 2,182; copy number 8: 1,201; copy number 9: 2,403; copy number 10: 548.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Y-A9GU-01A-11D-A381-01): tumor purity 0.76, ploidy 4.16, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,951 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,782,671–225,473,837, 1,792 genes, copy number 9 (broad region; genes not listed).
- chr2:20,386,386–20,861,661, 15 genes, copy number 9: SLC7A15P, RNA5SP86, RHOB, AC023137.1, Y_RNA, AC012065.1, NDUFAF2P1, HS1BP3, AC012065.2, HS1BP3-IT1, RPS25P3, GDF7, AC012065.3, LDAH, LINC02850.
- chr4:10,167,159–33,208,430, 221 genes, copy number 9 (broad region; genes not listed).
- chr7:8,433,609–8,752,961, 1 gene, copy number 10 (within-gene range 6–10): NXPH1.
- chr7:25,118,656–27,844,564, 90 genes, copy number 10 (broad region; genes not listed).
- chr7:27,873,785–27,876,546, 1 gene, copy number 10: AC004549.1.
- chr19:12,995,475–19,979,610, 366 genes, copy number 9 (broad region; genes not listed).
- chr19:39,553,034–39,738,029, 17 genes, copy number 10: AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC.
- chr19:53,299,051–58,605,223, 439 genes, copy number 10 (broad region; genes not listed).
- chr22:34,589,085–35,231,056, 9 genes, copy number 9 (within-gene range 6–9): AL021877.1, AL021877.2, Z82196.1, Z82196.2, LINC02885, ISX, LINC01399, Z99755.2, Z99755.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
